Somatic mutation profile of tumor specimen TCGA-DX-A7ET-01A (aliquot TCGA-DX-A7ET-01A-11D-A36J-09) from TCGA case TCGA-DX-A7ET, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 71.7 years (26,193 days).
Specimen TCGA-DX-A7ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cb8172f-d5e9-4233-a2c8-91de7c82b6f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7ET-10A (Blood Derived Normal), aliquot TCGA-DX-A7ET-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64129745-9c5e-488a-9b26-186d3ccf218e

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV99710835; called by muse, mutect2, varscan2
- ATP13A5 | c.2515C>G p.Q839E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100665410; called by muse, mutect2, varscan2
- C14orf39 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 44/108 reads (41%) | catalogued as COSV100407866; called by muse, mutect2, varscan2
- DNAJC11 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as rs558222069, COSV50012094, COSV99275669; called by muse, mutect2, varscan2
- FAM83G | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs751950262, COSV100525306; called by muse, varscan2
- FIG4 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100019990; called by muse, mutect2, varscan2
- HSPA1B | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV100989291; called by mutect2, varscan2
- JPH2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65906320; called by muse, mutect2, varscan2
- KIF17 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1484166382, COSV99929388; called by muse, mutect2
- MARK4 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99488517; called by muse, mutect2, varscan2
- MMP24 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.863); catalogued as rs376734021, COSV55768997, COSV99864047; called by muse, mutect2, varscan2
- NELL1 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs757482946, COSV54240995; called by muse, mutect2, varscan2
- OR4C11 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs1408130574, COSV100155393; called by muse, mutect2, varscan2
- OSMR | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as CM109127, COSV99953425; called by muse, mutect2
- PHKA1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263554; called by muse, mutect2, varscan2
- PLEKHM2 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs199779846, COSV101009160; called by muse, mutect2, varscan2
- PPIL6 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV101446758; called by muse, mutect2
- RALYL | c.306C>A p.N102K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs1251848243, COSV101569315; called by muse, mutect2, varscan2
- RNASE2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.076); catalogued as rs757362424, COSV100482032; called by muse, mutect2, varscan2
- RNF19A | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100347901; called by muse, mutect2
- ROBO3 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778491278, COSV101185114; called by muse, mutect2, varscan2
- SARDH | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs1429136058, COSV100898453; called by muse, mutect2
- SLC8A2 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99370168; called by muse, mutect2, varscan2
- TTLL10 | c.868C>T p.R290C (on ENST00000379289 / NM_001130045.2; = p.R217C on NM_153254.3) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs367856945; called by muse, mutect2, varscan2
- VCX2 | c.392T>A p.F131Y | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750804166, COSV100400049; called by muse, mutect2
- ZNF229 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 75/98 reads (77%) | catalogued as rs377446964, COSV52163535, COSV52165500; called by muse, mutect2, varscan2
- CLK1 | c.316_320del p.G106Kfs*5 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- TP53 | c.358_359insCTTA p.K120Tfs*2 | Nonsense Mutation (INS) | VAF 61/137 reads (45%) | called by mutect2, pindel, varscan2
- CEP78 | c.1536T>C p.N512= (on ENST00000424347 / NM_001349840.2; = p.N513= on NM_032171.3) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs1000793742, COSV99450699; called by muse, mutect2
- H4C3 | c.18A>G p.K6= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100619596; called by muse, mutect2, varscan2
- IPO4 | c.1887C>T p.S629= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100269139; called by muse, mutect2, varscan2
- OR4M1 | c.720C>G p.S240= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV100271330; called by muse, mutect2, varscan2
- PMP22 | c.384G>A p.S128= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs757027432, COSV56603120; called by muse, mutect2, varscan2
- TDRD7 | c.2295A>G p.P765= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100795728; called by muse, mutect2, varscan2
- VGLL1 | c.441T>C p.S147= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV101034675; called by muse, mutect2
